Somatic mutation profile of tumor specimen 0DPAOL from CCDI case PBCDFA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Craniopharyngioma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,134 days).
Specimen 0DPAOL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6350bd6e-f9fc-4491-89fb-1da189485bf4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPAOB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecc2faf5-5eca-4b68-a5b0-86fbc497fe6e

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 218/685 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COPB2 | c.1151G>C p.R384T | Missense Mutation (SNP) | VAF 37/676 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MYO18A | c.4553C>T p.S1518F | Missense Mutation (SNP) | VAF 236/795 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- SPEG | c.8163G>T p.W2721C | Missense Mutation (SNP) | VAF 32/1117 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC9A3 | c.1518-54C>T | Intron (SNP) | VAF 73/219 reads (33%) | catalogued as rs1423702226, COSV99376728; called by muse, mutect2, varscan2
